TCGA case TCGA-VS-A8Q9 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5798d741-c198-4c14-bcc2-e3b17caf1be3

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Brazil; Age at index: 79 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 79.1 years (28,881 days); Year of diagnosis: 2010; Method of diagnosis: Biopsy; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: MX; FIGO stage: Stage IB1; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 107 days; Days to treatment end: 148 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 149 days; Days to treatment end: 170 days; Treatment dose: 2,700 cGy; Treatment outcome: Complete Response; Number of fractions: 4; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 2,700 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: No; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Pharmaceutical Therapy, NOS, postoperative.

Follow-up (3 entries)
- Day 90 (prior to adjuvant therapy): ECOG performance status: 1.
- Days to follow up: 1,400 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,630 days (4.5 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Miscarriage.
- Timepoint category: Initial Diagnosis; Weight: 49 kg; Height: 150 cm; BMI: 21.8.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VS-A8Q9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 50 mg.
  Slide TCGA-VS-A8Q9-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-VS-A8Q9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VS-A8Q9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 8; Pregnancies count miscarriage: 4; Total pregnancy count: 12; Tobacco smoking history indicator: 1; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); New tumor event diagnosis indicator: No.
- Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: 3D conformal.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,630 days; disease-specific survival: no event (censored), 1,630 days; disease-free interval: no event (censored), 1,630 days; progression-free interval: no event (censored), 1,630 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VS-A8Q9-01A-12D-A37M-01): tumor purity 0.54, ploidy 3.87, whole-genome doublings 1.
